Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6541, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6541-01A (Primary Tumor).

[REDACTED]

Department of Cancer Pathology

[REDACTED]

[REDACTED]

Examination: Histopathological examination

[REDACTED] TCGA - D5 - 6541

[REDACTED]

[REDACTED]

Material: . Partial organ resection – descending colon

[REDACTED]

Physician in charge: [REDACTED]

Material collected on [REDACTED] Material received on [REDACTED]

Expected time of examination: up [REDACTED]

Clinical diagnosis: Cancer of the splenic flexure.

[REDACTED]

Examination performed on [REDACTED]

Macroscopic description:

17 cm length of intestine with perintestinal fat tissue sized 16 x 6 x 3 cm. Two cauliflower tumours sized 3.5 x 3 x 1.5 and 2 x 3 x 1.5 cm found in the mucosa. The tumours lie in one line covering the whole circumference. Lesions placed 4 cm from one of the excision lines and 2.5 cm from the opposite one. Macroscopically, the lesion invades through the muscular membrane.

Minimum side margin 3 cm.

Microscopic description:

Adenocarcinoma tubulopapillare (G1).

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae pericolicae.

Minimum side margin is 3 cm. Excision lines free of neoplastic lesions.

Sinus histiocytosis lymphonodorum (No XIII).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare bifocal coli. Tubulopapillar bifocal adenocarcinoma of the colon.

(G1, Dukes B, Astler-Coller B2, pT3, pN0).

[REDACTED]

[REDACTED]

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file d04e2b9a-b16b-4f8f-bac8-047c4bbc21cb (TCGA-D5-6541.93F340FA-2FE6-4D79-A8E8-7233C8C1B536.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).